MMRF case MMRF_2471 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/5461b1f9-b4d0-4f76-97c8-f8ea3940f29a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.6 years (26,170 days); ISS stage: III; Days to last known disease status: 724 days (2.0 years); Days to last follow up: 724 days (2.0 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 4 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 724.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 2): M Protein 4.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.969 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 12.3 mg/dL; Immunoglobulin G 79.2 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 5.7 µg/mL; Hemoglobin 7.25 mmol/L; Leukocytes 12 ×10⁹/L; Absolute Neutrophil 9.2 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.45 mmol/L; Albumin 32 g/L; Total Protein 10.7 g/dL; Glucose 6.66 mmol/L.
- Day 84 (ECOG 2): M Protein 2.4 g/dL; Immunoglobulin G 35.5 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.16 g/L; Hemoglobin 5.15 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.03 mmol/L; Albumin 27 g/L; Total Protein 7.7 g/dL; Glucose 6.77 mmol/L.
- Day 190 (ECOG 2): M Protein 1.1 g/dL; Immunoglobulin G 15 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.06 g/L; Hemoglobin 6.26 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 96 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.05 mmol/L; Albumin 32 g/L; Total Protein 5.6 g/dL; Glucose 4.46 mmol/L.
- Day 256 (ECOG 2): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.984 mg/dL; Immunoglobulin G 7.83 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.06 g/L; Hemoglobin 7.25 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.08 mmol/L; Albumin 34 g/L; Total Protein 5.2 g/dL; Glucose 4.35 mmol/L.
- Day 346 (ECOG 2): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Immunoglobulin G 8.53 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.06 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.15 mmol/L; Albumin 35 g/L; Total Protein 5.7 g/dL; Glucose 4.95 mmol/L.
- Day 458: M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Immunoglobulin G 8.15 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.06 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.13 mmol/L; Albumin 34 g/L; Total Protein 5.3 g/dL; Glucose 4.79 mmol/L.
- Day 515: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.26 mg/dL; Immunoglobulin G 7.29 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.13 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.1 mmol/L; Albumin 32 g/L; Total Protein 4.9 g/dL; Glucose 6 mmol/L.
- Day 717 (ECOG 2): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.4 mg/dL; Immunoglobulin G 7.28 g/L; Immunoglobulin A 1.15 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 6.26 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 418 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 1.98 mmol/L; Albumin 25 g/L; Total Protein 4.8 g/dL; Glucose 7.98 mmol/L.

Other clinical attributes
- Day -5: Weight: 146 kg; Height: 175 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2471_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_2471_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
